Somatic mutation profile of tumor specimen BA2843D (aliquot aq-BA2843D) from BEATAML1.0 case 2178, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, minimal differentiation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 84.8 years (30,982 days).
Specimen BA2843D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27217100-ccd9-4e43-bac9-7f0f7869161b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2159D (Solid Tissue Normal), aliquot aq-BA2159D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7df7115-1e4c-465c-9ce7-2933bcd0cb05

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Nonsense Mutation 2, Intron 1, Silent 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT4 | c.1774C>T p.R592C | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs375315719; called by muse, mutect2, varscan2
- GRIP2 | c.329C>T p.A110V (on ENST00000619221; = p.A13V on NM_001080423.4) | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.157); catalogued as rs747336735, COSV56122058; called by muse, varscan2
- SH3GL3 | c.757C>T p.R253* | Nonsense Mutation (SNP) | VAF 39/88 reads (44%) | catalogued as rs765453714, COSV61053899; called by muse, mutect2, varscan2
- TLL2 | c.286G>T p.G96C | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as COSV100780338; called by muse, varscan2
- GRIK2 | c.2700G>T p.R900S | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.284); called by muse, varscan2
- IGHD2-2 | chr14:105916823 del GTGGGCATAG | Missense Mutation (DEL) | VAF 13/40 reads (33%) | called by mutect2, varscan2
- WRNIP1 | c.1500C>A p.Y500* | Nonsense Mutation (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- IRF2BPL | c.1569G>T p.G523= | Silent (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- CLUHP11 | n.303C>A | RNA (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- RFX3 | c.474+6153T>C | Intron (SNP) | VAF 3/48 reads (6%) | catalogued as rs1420041718; called by muse, mutect2
